TCGA case TCGA-FD-A3SQ — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - University Of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3071cb51-dcf5-41f7-b047-afc2dcbf0aaf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Dead; Days to death: 1,423 days (3.9 years).

Diagnoses (8)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 62.1 years (22,687 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,423 days (3.9 years).
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: Yes; Lymph nodes positive: 5; Lymph nodes tested: 29.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 78 days; Days to treatment end: 151 days; Treatment outcome: Stable Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC). Age at diagnosis: 12.0 years (4,385 days); Days to diagnosis: -18,302 days (-50.1 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -18,302 days (-50.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2a.
5. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Sigmoid colon. Age at diagnosis: 64.8 years (23,678 days); Days to diagnosis: 991 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 991 days (2.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
6. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Pelvis, NOS. Age at diagnosis: 64.8 years (23,678 days); Days to diagnosis: 991 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 991 days (2.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
7. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 64.8 years (23,678 days); Days to diagnosis: 991 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 991 days (2.7 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 991 days (2.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
8. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Pelvis, NOS. Age at diagnosis: 65.2 years (23,809 days); Days to diagnosis: 1,122 days (3.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS, for recurrent disease.

Follow-up (6 entries)
- Day 991 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 991 days (2.7 years).
- Day 991 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Sigmoid colon; Days to recurrence: 991 days (2.7 years).
- Day 991 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 991 days (2.7 years).
- Day 991 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 991 days (2.7 years).
- Day 1,122 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 1,122 days (3.1 years).
- Days to follow up: 1,423 days (3.9 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 89 kg; Height: 196 cm; BMI: 23.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 60; Tobacco smoking quit year: 2008.
- Occupation duration years: 40; Occupation type: Transport and Storage Labourers.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Bladder Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FD-A3SQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-FD-A3SQ-01A-02-TSB: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FD-A3SQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FD-A3SQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: baggage handler at airport; Occupation primary: baggage handler at airport; Occupation primary industry: airline industry; Tobacco smoking history indicator: 4; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Lateral; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2a.
- Stage record, Gleason grading: Gleason score: 6.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: 31.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Resection.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had synchronous prostate cancer and reported a prior breast cancer. No radiation or systemic chemotherapy.
- Synchronous malignancy: Patient had synchronous prostate cancer and reported a prior breast cancer. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,423 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,423 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 991 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FD-A3SQ-01A-21D-A22Y-01): tumor purity 0.5, ploidy 1.97, whole-genome doublings 0.
